Gene-level copy-number profile of tumor specimen TCGA-QH-A6CV-01A from TCGA case TCGA-QH-A6CV, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 51.9 years (18,955 days).
Specimen TCGA-QH-A6CV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.cb996b13-67bc-45cc-af13-e965d94498b0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QH-A6CV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6c268cff-1f8e-41d3-ba55-f143010680f6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,791; copy number 3: 8,866; copy number 4: 25,996; copy number 5: 9,594; copy number 6: 610; copy number 7: 2,365; copy number 8: 4,848; copy number 9: 2,628; copy number 10: 21; copy number 16: 36; copy number 22: 40; copy number 26: 3; copy number 46: 18; copy number 107: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QH-A6CV-01A-11D-A31K-01): tumor purity 0.57, ploidy 4.63, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,749 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:95,297,327–95,991,831, 36 genes, copy number 16 (within-gene range 3–16): KCNIP3, FABP7P2, FAHD2A, AC009238.3, AC009238.2, AC009238.1, UBTFL5, AC133104.2, AC133104.1, TRIM43B, AC009237.11, AC009237.1, AC009237.10, AC009237.2, TRIM64FP, AC009237.14, AC009237.3, AC009237.8, AC009237.15, AC009237.5, OR7E102P, TRIM51JP, AC009237.16, AC009237.4, TRIM43, AC009237.7, AC009237.13, AC009237.12, UBTFL3, AC009237.17, AC009237.6, AC009237.9, AC008268.1, GPAT2P1, LINC00342, ANKRD36C.
- chr5:58,198–168,264,157, 2,620 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr7:54,933,699–55,211,628, 3 genes, copy number 107: AC006971.1, EGFR, EGFR-AS1.
- chr12:4,097,451–4,694,317, 18 genes, copy number 46: HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9.
- chr12:57,434,784–57,896,846, 43 genes, copy number 22–26 (within-gene range 14–26): INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3.
- chr12:109,713,825–109,888,467, 8 genes, copy number 9 (within-gene range 5–9): FAM222A, FAM222A-AS1, TRPV4, MIR4497, GLTP, AC007834.2, RN7SL441P, AC007834.1.
- chr19:11,368,123–11,619,161, 20 genes, copy number 10: AC024575.1, SWSAP1, EPOR, RGL3, Y_RNA, CCDC151, PRKCSH, ELAVL3, AC008481.3, ZNF653, MIR7974, ECSIT, RN7SL833P, AC008481.2, AC008481.1, CNN1, ELOF1, ZNF627, ACP5, GAPDHP76.
- chr19:11,648,364–11,652,877, 1 gene, copy number 10: ZNF887P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
